Somatic mutation profile of tumor specimen C3N-03810-01 (aliquot CPT0285300006) from CPTAC case C3N-03810, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,750 days).
Specimen C3N-03810-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6c1e63a-4541-470d-af7a-1b8bfe91eb80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03810-31 (Blood Derived Normal), aliquot CPT0285330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f27eda-59b9-4fa4-9e78-30657ae1fc23

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Nonsense Mutation 3, Intron 3, Splice Region 1, In Frame Ins 1, Splice Site 1, 5'Flank 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 76/417 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771959876, COSV56849611, COSV56858106; called by muse, mutect2, varscan2
- APOO | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs373029808, COSV101004914; called by muse, mutect2, varscan2
- C8B | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 74/475 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1217153736; called by muse, mutect2, varscan2
- CACNA2D3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs200467931; called by muse, mutect2, varscan2
- LINC01098 | n.518+4C>T | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as rs369388738; called by muse, mutect2
- LYST | c.10966G>A p.G3656R | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101089708; called by muse, mutect2, varscan2
- MYCN | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 98/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257406, COSV55259752; called by muse, mutect2, varscan2
- NUDT3 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 104/561 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1377172787; called by muse, mutect2, varscan2
- PABPC5 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs779133384, COSV57039569, COSV57042673; called by muse, mutect2, varscan2
- RFWD3 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs747018311, COSV100736267; called by muse, mutect2, varscan2
- SVEP1 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs376146001; called by muse, mutect2
- TDRD9 | c.3451G>A p.G1151R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752004479; called by muse, mutect2, varscan2
- TMCO3 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64808368; called by muse, mutect2, varscan2
- ADGRV1 | c.6701T>A p.L2234* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- ATP2C2 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by mutect2, varscan2
- BMI1 | c.570+1G>C p.X190_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- CA12 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC180 | c.2201_2202insAGAGGA p.E735_E736dup | In Frame Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel
- CDH5 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 75/533 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM186A | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FBXO40 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- FOXO6 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GDF10 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- GTPBP2 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- HERC4 | c.2650G>A p.A884T (on ENST00000395198 / NM_022079.3; = p.A876T on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2
- HTR3D | c.355C>A p.L119I (on ENST00000382489 / NM_001163646.2; = p.L58I on NM_001145143.1) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MYO6 | c.2815A>G p.R939G | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PTGFRN | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- RTL1 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2
- SNAPC4 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNRC6B | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- TP53BP2 | c.1867C>T p.Q623* (on ENST00000343537 / NM_001031685.3; = p.Q494* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 53/309 reads (17%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- UTP18 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 46/554 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- WASH6P | c.6T>G p.S2R | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious, low confidence (0); called by mutect2, varscan2
- WASH6P | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious, low confidence (0); called by mutect2, varscan2
- ARHGAP39 | c.2929C>T p.L977= (on ENST00000276826 / NM_001308208.2; = p.L1008= on NM_025251.2) | Silent (SNP) | VAF 43/246 reads (17%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.2373C>T p.H791= | Silent (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- CYP4B1 | c.645C>T p.V215= | Silent (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- HCN1 | c.204C>T p.G68= | Silent (SNP) | VAF 48/271 reads (18%) | catalogued as rs1561248539; called by muse, mutect2, varscan2
- IGHMBP2 | c.39A>G p.Q13= | Silent (SNP) | VAF 125/656 reads (19%) | called by muse, mutect2, varscan2
- INSM2 | c.984C>T p.A328= | Silent (SNP) | VAF 64/470 reads (14%) | called by muse, mutect2, varscan2
- LAMA1 | c.4695G>C p.L1565= | Silent (SNP) | VAF 40/233 reads (17%) | catalogued as COSV67544135; called by muse, mutect2, varscan2
- LARGE1 | c.87G>T p.L29= | Silent (SNP) | VAF 80/488 reads (16%) | called by muse, mutect2, varscan2
- NKD2 | c.1086G>A p.P362= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs567751276; called by muse, mutect2, varscan2
- PTCH2 | c.1869G>A p.L623= | Silent (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- TRPV4 | c.984G>T p.L328= | Silent (SNP) | VAF 105/717 reads (15%) | called by muse, mutect2, varscan2
- USH2A | c.13833G>A p.A4611= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs760266483; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP1 | c.81C>A p.P27= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- ZNF423 | c.777G>A p.L259= (on ENST00000563137 / NM_001379286.1; = p.L251= on NM_015069.4) | Silent (SNP) | VAF 68/461 reads (15%) | called by muse, mutect2, varscan2
- EIPR1 | c.516+5358C>T | Intron (SNP) | VAF 45/306 reads (15%) | catalogued as rs776416811; called by muse, mutect2, varscan2
- FADS2 | c.745-10C>G | Intron (SNP) | VAF 25/165 reads (15%) | called by muse, mutect2, varscan2
- HAS3 | chr16:69118388 C>G | 3'Flank (SNP) | VAF 85/483 reads (18%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-3888T>C | Intron (SNP) | VAF 96/470 reads (20%) | catalogued as rs1567770819; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158849 C>T | 5'Flank (SNP) | VAF 33/194 reads (17%) | catalogued as rs1280818622; called by muse, mutect2, varscan2
- ZNF208 | c.*509G>A | 3'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
